Surgical pathology report (de-identified scan), TCGA case TCGA-97-8177, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8177-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE: [REDACTED]

SPECIMENS:

1. STATION 7 LYMPH NODE
2. STATION 11 LYMPH NODE
3. STATION 12 LYMPH NODE
4. LUNG, LEFT LOWER LOBECTOMY
5. STATION 5 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Special Stains Results

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

DIAGNOSIS:

1. LYMPH NODE, STATION 7: BIOPSY

- ADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

2. LYMPH NODE, STATION 11: BIOPSY

- FRAGMENTS OF ANTHRACOTIC LYMPH NODE, NEGATIVE FOR CARCINOMA.

3. LYMPH NODE, STATION 12: BIOPSY

- FRAGMENTS OF ANTHRACOTIC LYMPH NODE, NEGATIVE FOR CARCINOMA.

4. LUNG, LEFT, LOWER LOBE: LOBECTOMY

- ADENOCARCINOMA OF MIXED SUB-TYPE (4 CM), MODERATELY DIFFERENTIATED

(SEE SUMMARY).

- BRONCHOVASCULAR MARGIN, NEGATIVE FOR CARCINOMA.

- BENIGN PERIBRONCHIAL ANTHRACOTIC LYMPH NODES, NEGATIVE FOR CARCINOMA.

5. LYMPH NODE, STATION 5: BIOPSY

- FRAGMENTS OF ANTHRACOTIC LYMPH NODE, NEGATIVE FOR CARCINOMA.

Specimens: 1: STATION 7 LYMPH NODE

2: STATION 11 LYMPH NODE

3: STATION 12 LYMPH NODE

4: LUNG, LEFT LOWER LOBECTOMY

5: STATION 5 LYMPH NODE

[page 2 of 8]
LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

left, lower

Procedure: Lobectomy

Specimen Laterality: Left

Tumor Site: Lower lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

4cm

Additional Dimension (cm): 4cm x 3cm

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Bronchial Margin Involvement by Squamous Cell Carcinoma in situ (CIS):

Squamous cell carcinoma in situ (CIS) not identified at bronchial margin

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Present

SPECIAL STUDIES

Epidermal Growth Factor Receptor (EGFR) Analysis Results (specify method): to follow

KRAS Mutational Analysis (specify results): to follow

STAGE (pTNM)

Primary Tumor (pT):

pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Emphysema

[page 3 of 8]
small intraparenchymal scar and meningoethial-like nodule

Comment(s):

The adenocarcinoma is of mixed subtype, displaying papillary and acinar patterns, and is associated with scar. Although predominantly moderately differentiated, small foci of pleomorphic poorly differentiated tumor cells are present. A TTF1 immunostain is positive, compatible with pulmonary origin. Venous invasion is present. Perineural infiltration is seen.

[REDACTED]

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

Lung cancer

MACROSCOPIC DESCRIPTION:

The specimen is received fresh in five parts, each labeled with the patient's name.

1. Part one is labeled 'station 7 lymph node'. It consists of a 0.7 x 0.6 x 0.3 cm irregular portion of pink yellow soft adipose tissue. Entirely submitted in one cassette.
2. Part two is labeled 'station 11 lymph node'. It consists of a 1.5 x 1 x 0.6 cm aggregate of black soft rubbery anthracotic lymphoid tissue. Entirely submitted in one cassette.
3. Part three is labeled 'station 12 lymph node'. It consists of 1 x 0.6 x 0.2 cm aggregate of black soft rubbery anthracotic lymphoid tissue admixed with pink yellow soft adipose tissue. Entirely submitted in one cassette.
4. Part four is labeled 'left lower lobectomy'. It consists of a left lower lobectomy specimen measuring 15 x 13 x 5 cm. The bronchial margin is (1.6 cm diameter) and vascular margin at the hilum are grossly free of tumor. The pleura is grey-pink, glistening and mottled; a 3 cm puckered area is noted at the upper outer aspect of the lobe (inked in black). A staple line measures 5 cm in length, which is shaved and the pleura around it is inked in black. Beneath the puckered area, 1.2 cm from the bronchial resection margin; a 4 x 4 x 3 cm grey-white firm tumor with ill-defined borders is noted. The remainder of the parenchyma is pink-red, blotchy and crepitant. Multiple peribronchial anthracotic firm lymph nodes, ranging from 0.2 up to 0.7 cm in greatest dimension, are identified from the hilar area. Representative sections are

[page 4 of 8]
submitted.

5. Part five is labeled 'station 5 lymph node'. It consists of a 2.3 x 1.8 x 0.8 cm aggregate of black soft rubbery anthracotic lymphoid tissue admixed with yellow soft adipose tissue. Entirely submitted in one cassette.

[REDACTED]

SUMMARY OF SECTIONS:

1A entirely submitted
2A entirely submitted
3A entirely submitted
4A vascular margin at the hilar region, shaved
4B bronchial margin, shaved
4C-4F tumor, bisected
4G staple line margin
4H-4I non-tumor parenchyma
4J lymph nodes
5A entirely submitted

SPECIAL PROCEDURES:

TTF1

Final Diagnosis performed by

[REDACTED]

ADDENDUM 1:

Visceral pleural invasion is not seen on an elastic stain.

Addendum #1 performed by

[REDACTED]

Electronically signed

[REDACTED]

ADDENDUM #2:

INTEGRATED ONCOLOGY

EGFR Mutation Analysis

[REDACTED]

Body Site: Lung

[page 5 of 8]
Clinical Data: Adenocarcinoma

RESULTS: Positive for the L858R mutation in Exon 21.

INTERPRETATION: The L858R mutation is reported to correlate with responsiveness to EGFR tyrosine kinase inhibitor therapies in patients with non-small-cell lung carcinoma.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 8% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[page 6 of 8]
REFERENCES:

[REDACTED]

DISCLAIMER:

The test was developed and its performance characteristics determined by [REDACTED] LLC. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by:

[REDACTED]

Addendum #2 performed by

[REDACTED]

ADDENDUM #3:

INTEGRATED ONCOLOGY
MOLECULAR ONCOLOGY
KRAS MUTATION ANALYSIS

[REDACTED]

Body Site: Lung
Clinical Data: Adenocarcinoma

RESULTS: Wild-type gene.

[page 7 of 8]
INTERPRETATION:

No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of non-small-cell lung cancer (NSCLC) patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[page 8 of 8]
[REDACTED]

The test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions. [REDACTED] is a business unit of [REDACTED] a wholly-owned subsidiary of [REDACTED].

Electronically signed by: [REDACTED]

Date: [REDACTED]

[REDACTED]

Addendum #3 performed by [REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED] Department of Pathology.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file c21d060a-5b25-4fe1-8555-15ce76b857a6 (TCGA-97-8177.ADDBE4E2-114D-4E38-AA21-C3E9695DA8FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).